Somatic mutation profile of tumor specimen 0DDKDD from CCDI case PBBMLJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.4 years (2,333 days).
Specimen 0DDKDD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa832a8-4ef4-416c-881b-278ffb435bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDKDE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df388c17-8a20-4178-81c2-2b7122dc906c

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.4873A>G p.I1625V | Missense Mutation (SNP) | VAF 186/284 reads (65%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs777531943; called by muse, varscan2
- TMEM247 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); called by muse, varscan2
- USHBP1 | c.203+7C>A | Splice Region (SNP) | VAF 86/350 reads (25%) | called by muse, varscan2
- ACBD4 | c.324G>A p.V108= | Silent (SNP) | VAF 90/302 reads (30%) | catalogued as rs779834848, COSV58853943; called by muse, varscan2
- BTBD1 | c.33G>A p.E11= | Silent (SNP) | VAF 200/306 reads (65%) | called by muse, varscan2
- CSMD1 | c.9303G>A p.P3101= (on ENST00000520002; = p.P3100= on NM_033225.6) | Silent (SNP) | VAF 128/888 reads (14%) | catalogued as rs761115346, COSV59281702, COSV59317968; called by muse, varscan2
- PTPN14 | c.1314G>A p.S438= | Silent (SNP) | VAF 150/669 reads (22%) | catalogued as rs192277867; called by muse, varscan2
- MEIS2 | c.490-18C>A | Intron (SNP) | VAF 256/440 reads (58%) | called by muse, varscan2
- VGLL4 | c.*8G>A | 3'UTR (SNP) | VAF 74/187 reads (40%) | catalogued as rs370862899; called by muse, varscan2
